Gene-level copy-number profile of tumor specimen TCGA-NP-A5GY-01A from TCGA case TCGA-NP-A5GY, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 75.2 years (27,464 days).
Specimen TCGA-NP-A5GY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 685cf63f-467d-4e66-b6d3-85854d191ea0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-NP-A5GY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/1cf9f478-2990-4f2c-8c0a-4505177451b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 31; copy number 2: 57,960; copy number 3: 404.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:76,959,835–77,043,775, 1 gene (within-gene range 0–2): DTX2P1-UPK3BP1-PMS2P11.
- chr7:76,978,617–77,032,361, 5 genes (within-gene range 0–2): DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 31. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
